Somatic mutation profile of tumor specimen TCGA-XF-AAMW-01A (aliquot TCGA-XF-AAMW-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.1 years (28,903 days).
Specimen TCGA-XF-AAMW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7822a2ad-2a14-414f-8a9d-710eee6dfe45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMW-10A (Blood Derived Normal), aliquot TCGA-XF-AAMW-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59abafe-763a-4678-9b02-9c6949229cf6

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.16342C>T p.P5448S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60910749; called by muse, varscan2
- ATG7 | c.2003del p.V668Gfs*9 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV61611615, COSV61611810; called by mutect2, pindel, varscan2
- EFEMP1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV62615429; called by muse, mutect2, varscan2
- FSTL3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV99383950; called by muse, mutect2, varscan2
- GAREM1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52507180; called by muse, mutect2, varscan2
- GCFC2 | c.2278A>C p.N760H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58080141; called by muse, mutect2, varscan2
- GGTLC1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.411); catalogued as COSV53846786; called by muse, mutect2, varscan2
- HACE1 | c.2705G>A p.G902D | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53500199; called by muse, mutect2, varscan2
- HDAC11 | c.105T>A p.H35Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169722225, COSV55472648; called by muse, varscan2
- LTBP2 | c.3403+1G>C p.X1135_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as COSV56206178; called by muse, mutect2, varscan2
- MCCC2 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as COSV60153193; called by muse, mutect2, varscan2
- MYOT | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 39/125 reads (31%) | catalogued as COSV99295896; called by muse, mutect2, varscan2
- OR52W1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1021537512, COSV60950589, COSV60950961; called by muse, mutect2, varscan2
- PGM2 | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67938548; called by muse, mutect2, varscan2
- PIP5K1C | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs750011345, COSV58950910, COSV58954618; called by muse, mutect2, varscan2
- PTPN3 | c.586A>C p.S196R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as COSV52703053; called by muse, mutect2, varscan2
- SALL1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV51754926; called by muse, mutect2, varscan2
- SLC27A3 | c.1840G>A p.G614R (on ENST00000271857; = p.G486R on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55162662; called by muse, mutect2, varscan2
- TAAR1 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV51587978, COSV99257800; called by muse, mutect2, varscan2
- THBS2 | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV64677680; called by muse, mutect2, varscan2
- TP53 | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as COSV52675685, COSV52909445; called by muse, mutect2, varscan2
- CASP9 | c.354A>G p.P118= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1267574912, COSV61601083; called by muse, mutect2, varscan2
- DMBX1 | c.501C>T p.P167= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV63601764; called by muse, mutect2, varscan2
- DOK6 | c.372C>A p.P124= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs368721580, COSV66927938; called by muse, mutect2, varscan2
- GOLGA4 | c.6615T>C p.P2205= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1476189051, COSV62709789; called by muse, mutect2, varscan2
- MMP14 | c.750C>T p.S250= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV61287726; called by muse, mutect2, varscan2
- OR8U1 | c.24G>A p.Q8= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1020591866, COSV100163804, COSV56414852; called by muse, mutect2
- SLCO4A1 | c.1059G>A p.K353= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV53889757; called by muse, mutect2, varscan2
- WDR91 | c.1431C>G p.L477= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60368992; called by muse, mutect2, varscan2
- ZFYVE26 | c.6069G>A p.V2023= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV61325711; called by muse, varscan2
- ZNF8 | c.1440T>C p.S480= | Silent (SNP) | VAF 69/206 reads (33%) | catalogued as COSV52186878; called by muse, mutect2, varscan2
